Somatic mutation profile of tumor specimen TARGET-10-PASHNK-09A (aliquot TARGET-10-PASHNK-09A-01D) from TARGET case TARGET-10-PASHNK, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,416 days).
Specimen TARGET-10-PASHNK-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 00fa1938-85d1-439c-b6f7-16f82861f1d6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASHNK-10A (Blood Derived Normal), aliquot TARGET-10-PASHNK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e78fab5b-9f67-4be7-b071-80612752f549

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Nonsense Mutation 2, Frame Shift Ins 2, Frame Shift Del 2, Intron 2, Silent 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1268G>T p.G423V (on ENST00000281708 / NM_001349798.2; = p.G343V on NM_018315.5) | Missense Mutation (SNP) | VAF 35/81 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157879635, COSV55892390, COSV99657129; called by muse, mutect2, varscan2
- RUNX1 | c.404G>A p.R135K (on ENST00000344691 / NM_001001890.3; = p.R162K on NM_001754.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1057519750, COSV55868310; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- ADGRL2 | c.2237C>G p.T746S (on ENST00000370717 / NM_001366005.1; = p.T733S on NM_012302.4) | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV54679462; called by muse, mutect2, varscan2
- ASXL2 | c.2750C>A p.S917* | Nonsense Mutation (SNP) | VAF 43/93 reads (46%) | catalogued as COSV55459077, COSV55464030; called by muse, mutect2, varscan2
- CCNF | c.1884C>T p.D628= | Splice Region (SNP) | VAF 10/17 reads (59%) | catalogued as rs761621306; called by muse, varscan2
- CNGA2 | c.1277G>A p.R426Q | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV61704097; called by muse, mutect2, varscan2
- DNM2 | c.2372C>G p.P791R (on ENST00000355667 / NM_001005360.3; = p.P787R on NM_004945.3) | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.994); catalogued as rs780738840, COSV53035151; called by mutect2, varscan2
- KCNH3 | c.2773G>A p.G925R | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.686); catalogued as COSV57792030; called by muse, mutect2, varscan2
- KRTAP10-4 | c.928T>C p.S310P | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs782638394, COSV59972457, COSV59972505; called by muse, mutect2, varscan2
- MTA1 | c.939T>A p.D313E | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV100495238, COSV58759065; called by muse, mutect2, varscan2
- MYB | c.41_42insCCCT p.E14Dfs*4 | Frame Shift Ins (INS) | VAF 14/30 reads (47%) | catalogued as COSV57197694; called by mutect2, varscan2
- NOTCH1 | c.5146T>C p.Y1716H | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53075007; called by muse, mutect2, varscan2
- NOTCH1 | c.5039T>C p.I1680T | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2
- PHF6 | c.70dup p.R24Kfs*12 | Frame Shift Ins (INS) | VAF 55/78 reads (71%) | catalogued as rs1372900096, COSV99045873; called by mutect2, pindel, varscan2
- SLC14A2 | c.90G>A p.W30* | Nonsense Mutation (SNP) | VAF 39/64 reads (61%) | catalogued as COSV54912418; called by muse, mutect2, varscan2
- SORBS1 | c.3364G>A p.E1122K | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.137); catalogued as rs769874306, COSV53359079; called by muse, mutect2, varscan2
- TMEM62 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53042274; called by muse, mutect2, varscan2
- TRIOBP | c.2090G>A p.R697K | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV100730727, COSV60381703; called by muse, mutect2, varscan2
- DNM2 | c.2377del p.L793* (on ENST00000355667 / NM_001005360.3; = p.L789* on NM_004945.3) | Frame Shift Del (DEL) | VAF 14/42 reads (33%) | called by mutect2, pindel, varscan2
- MYB | c.44_50del p.D15Gfs*35 | Frame Shift Del (DEL) | VAF 16/30 reads (53%) | called by mutect2, varscan2
- KCNH5 | c.1887C>T p.N629= | Silent (SNP) | VAF 26/46 reads (57%) | catalogued as rs373387419; ClinVar: likely benign; called by muse, mutect2, varscan2
- MUC2 | c.1129C>T p.L377= | Silent (SNP) | VAF 26/56 reads (46%) | catalogued as COSV100364517; called by muse, mutect2, varscan2
- HES4 | c.*88_*89insCCCTTTACAATTG | 3'UTR (INS) | VAF 9/15 reads (60%) | called by mutect2, varscan2*
- KCNH2 | c.1946-24G>A | Intron (SNP) | VAF 14/25 reads (56%) | catalogued as rs750045237; called by muse, varscan2
- SCN4A | c.1607-48C>T | Intron (SNP) | VAF 15/35 reads (43%) | catalogued as rs764116591; called by muse, mutect2, varscan2
